Gene-level copy-number profile of tumor specimen TCGA-DX-A3U9-01A from TCGA case TCGA-DX-A3U9, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 84.9 years (31,010 days).
Specimen TCGA-DX-A3U9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.325289cc-4283-4b48-ae26-83c8cf5c475a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A3U9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eb214833-a5b0-44d8-8f40-7d34e4571703

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 60; copy number 1: 23,468; copy number 2: 33,534; copy number 3: 2,019; copy number 4: 682; copy number 6: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A3U9-01A-11D-A306-01): tumor purity 0.91, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:74,120,255–74,150,842, 1 gene (within-gene range 0–1): AP3M1.
- chr10:74,344,550–74,344,805, 1 gene: TIMM9P1.
- chr10:87,659,613–89,556,641, 45 genes (within-gene range 0–1): PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1.
- chr12:66,767–442,642, 13 genes: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 51 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:76,869,601–77,638,369, 1 gene, copy number 6 (within-gene range 1–6): KCNMA1.
- chr10:77,313,941–79,067,895, 29 genes, copy number 6 (within-gene range 1–6): AL731575.1, KCNMA1-AS3, COX6CP15, RNA5SP321, AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A, RPS24, GNAI2P2, AL731555.1, AC012560.1, LINC00595, AC010163.3, AC010163.1, AC010163.2, SNORA71, AL583852.1, AC016820.1, ZMIZ1-AS1, AL356753.1.
- chr10:91,033,157–92,030,325, 18 genes, copy number 6: LINC00502, DDX18P6, NUDT9P1, AL731553.1, PCGF5, HECTD2, AL161798.1, RPS27P1, PPP1R3C, GAPDHP28, FAF2P1, TNKS2-AS1, TNKS2, SRP9P1, AL359198.2, FGFBP3, AL359198.1, BTAF1.
- chr10:92,076,242–92,138,370, 3 genes, copy number 6: AL365398.1, SDHCP2, EIF4A1P8.

Autosomal genes at a single copy (total copy number 1): 21,047. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
